Somatic mutation profile of tumor specimen TARGET-30-PAPVXS-01A (aliquot TARGET-30-PAPVXS-01A-01D) from TARGET case TARGET-30-PAPVXS, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.7 years (1,366 days).
Specimen TARGET-30-PAPVXS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b512ac0-89cb-4426-a3fe-a363d9a705b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPVXS-10A (Blood Derived Normal), aliquot TARGET-30-PAPVXS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95c21c40-8bd0-4bc2-8706-d7da48123d39

The open-access MAF lists 22 somatic variants for this specimen: 13 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 7, Nonsense Mutation 2, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC104389.6 | c.383T>A p.L128Q | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.945); catalogued as COSV57964511; called by muse, mutect2, varscan2
- BTAF1 | c.4493C>T p.P1498L | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56438597; called by muse, mutect2, varscan2
- CES1 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs746693909, COSV62089827; called by muse, mutect2, varscan2
- CFH | c.3179T>C p.V1060A | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as CM045281, COSV66412872; called by muse, mutect2, varscan2
- DGKI | c.810C>G p.F270L | Missense Mutation (SNP) | VAF 88/253 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs770468901, COSV55973144; called by muse, mutect2, varscan2
- MYO3A | c.824G>C p.R275P | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56346989; called by muse, mutect2, varscan2
- NFATC2 | c.854C>A p.P285H | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.617); catalogued as COSV65360461; called by muse, mutect2, varscan2
- OTOA | c.916C>T p.Q306* | Nonsense Mutation (SNP) | VAF 20/59 reads (34%) | catalogued as rs1288292297, COSV53763273; called by muse, mutect2, varscan2
- PIK3R5 | c.1153G>T p.D385Y | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52658264; called by muse, mutect2, varscan2
- RXFP3 | c.450C>A p.F150L | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV57505393, COSV57508004; called by muse, mutect2
- SPTA1 | c.367C>A p.H123N | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV63758571; called by muse, mutect2, varscan2
- TET2 | c.2144A>G p.N715S | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs774556296, COSV54431162; called by muse, mutect2, varscan2
- VN1R2 | c.648C>A p.C216* | Nonsense Mutation (SNP) | VAF 27/59 reads (46%) | catalogued as COSV59037436; called by muse, mutect2, varscan2
- BTD | c.1503G>T p.L501= | Silent (SNP) | VAF 45/121 reads (37%) | catalogued as COSV57730423; called by muse, mutect2, varscan2
- DNAH17 | c.6978G>T p.L2326= | Silent (SNP) | VAF 22/241 reads (9%) | catalogued as rs1250976339; called by muse, mutect2
- HLCS | c.1494C>T p.I498= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as rs749728724, COSV60797771; called by muse, mutect2, varscan2
- KCNMB3 | c.210C>A p.V70= | Silent (SNP) | VAF 34/127 reads (27%) | catalogued as COSV58571541; called by muse, mutect2, varscan2
- RTTN | c.5520A>G p.Q1840= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV55351348; called by muse, mutect2, varscan2
- SPOCD1 | c.2223G>T p.V741= | Silent (SNP) | VAF 84/228 reads (37%) | catalogued as COSV57099642; called by muse, mutect2, varscan2
- TEK | c.1935C>A p.I645= | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as COSV66233835; called by muse, mutect2, varscan2
- AGAP7P | n.1667G>T | RNA (SNP) | VAF 48/257 reads (19%) | called by muse, mutect2, varscan2
- TTN | c.10361-4584A>G | Intron (SNP) | VAF 25/61 reads (41%) | catalogued as COSV60311017; called by muse, mutect2, varscan2
